Gene-level copy-number profile of tumor specimen TCGA-UB-A7MB-01A from TCGA case TCGA-UB-A7MB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 24.5 years (8,951 days).
Specimen TCGA-UB-A7MB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.8f39c01c-ddd1-4921-b060-36f1b87ddcc4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UB-A7MB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/014df4c3-a759-4c04-9f0a-b33f243ee5ed

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 10,794; copy number 2: 47,008; copy number 3: 455; copy number 4: 42; copy number 5: 1,418.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UB-A7MB-01A-11D-A33P-01): tumor purity 0.93, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 88 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–4,348,392, 55 genes (within-gene range 0–1): WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, AL358976.1, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL358053.1, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1.
- chr10:133,453,928–133,761,125, 27 genes (within-gene range 0–1): SCART1, OR7M1P, CYP2E1, AL161645.1, AL161645.2, SYCE1, AL731769.2, OR6L1P, AL731769.1, FRG2B, RARRES2P2, AGGF1P2, CLUHP5, DUX4L28, DUX4L25, DUX4L24, DUX4L23, DUX4L22, DUX4L21, DUX4L20, DUX4L29, DUX4L10, DUX4L11, DUX4L12, DUX4L13, DUX4L14, DUX4L15.
- chr12:133,106,817–133,214,832, 6 genes (within-gene range 0–1): ZNF891, AC026786.2, RPL23AP67, ZNF10, AC026786.1, ZNF268.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,418 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–196,065,235, 1,418 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
